Somatic mutation profile of tumor specimen MBCProject_0375_T1_C_WES (aliquot MBCProject_0375_T1_C_WES_1) from CMI case MBCProject_0375, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0375_T1_C_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a927dcb6-3a0b-451a-9a20-6558808a9882.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0375_SALIVA (Saliva), aliquot MBCProject_0375_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/932ef890-8066-4f6d-80a2-d0cd158c6928

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF25 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1350372396; called by muse, mutect2, varscan2
- TUBE1 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868930152; called by muse, mutect2
- BMP2K | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OR6K3 | c.904C>T p.P302S (on ENST00000368146; = p.P286S on NM_001005327.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC16A2 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- ALDH1L2 | c.648A>G p.P216= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- PDX1 | c.267G>A p.Q89= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- TBPL2 | c.231G>A p.P77= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs568763103; called by muse, mutect2, varscan2
- INPP5F | c.612+32C>T | Intron (SNP) | VAF 3/14 reads (21%) | catalogued as rs757628686; called by mutect2, varscan2
